Gene-level copy-number profile of tumor specimen ALCH-B46S-TTP1-A from ALCHEMIST case ALCH-B46S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.6 years (25,772 days).
Specimen ALCH-B46S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5b30bd3e-2bfc-43a6-b24d-ab56d8432011.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B46S-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/648f1d62-d2ec-4203-98b8-9435bb3bd672

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 1,061; copy number 2: 56,448; copy number 3: 818; copy number 4: 47; copy number 5: 4; copy number 6: 8; copy number 10: 3; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:42,762,481–42,792,593, 2 genes: OXER1, HAAO.
- chr2:232,343,116–232,351,309, 2 genes (within-gene range 0–2): NRBF2P6, ECEL1P3.
- chr20:62,332,487–62,332,557, 1 gene (within-gene range 0–5): MIR4758.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:136,612,024–136,617,181, 1 gene, copy number 5: LINC01451.
- chr9:136,673,143–136,687,457, 1 gene, copy number 5: AGPAT2.
- chr9:136,754,386–136,810,042, 7 genes, copy number 6 (within-gene range 3–6): LCN8, LCN15, ATP6V1G1P3, TMEM141, AL355987.3, CCDC183, AL355987.4.
- chr9:136,803,927–136,808,848, 1 gene, copy number 6 (within-gene range 3–6): CCDC183-AS1.
- chr19:1,228,287–1,259,140, 4 genes, copy number 10–12 (within-gene range 3–12): CBARP, AC004221.1, ATP5F1D, MIDN.
- chr20:62,307,955–62,367,312, 1 gene, copy number 5 (within-gene range 0–5): LAMA5.
- chr20:62,352,995–62,356,480, 1 gene, copy number 5: LAMA5-AS1.

Autosomal genes at a single copy (total copy number 1): 907. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
